Somatic mutation profile of tumor specimen TCGA-MA-AA3W-01A (aliquot TCGA-MA-AA3W-01A-11D-A387-09) from TCGA case TCGA-MA-AA3W, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 54.9 years (20,066 days).
Specimen TCGA-MA-AA3W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c781fc88-fedc-4159-be11-13eb00265740.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MA-AA3W-10A (Blood Derived Normal), aliquot TCGA-MA-AA3W-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc7ace08-b114-4a0c-be36-01fdb1c28ce2

The open-access MAF lists 71 somatic variants for this specimen: 59 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 49, Silent 12, Nonsense Mutation 5, Splice Site 2, Splice Region 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJB1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs863224973, CM960751, COSV100661259; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSF2 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs780707588, COSV99366130; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3934G>A p.A1312T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV99718069, COSV99721266; called by muse, mutect2, varscan2
- ARHGAP45 | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV104398967; called by muse, mutect2
- ARHGAP5 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100565186; called by muse, mutect2, varscan2
- BCL9 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782465178, COSV52349605; called by muse, mutect2
- CHPT1 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57534041; called by muse, mutect2
- CLEC3A | c.578G>A p.R193H (on ENST00000651443; = p.R184H on NM_005752.6) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs201495730, COSV55221440, COSV55224438; called by muse, mutect2, varscan2
- CLUH | c.3147G>C p.M1049I (on ENST00000435359; = p.M1088I on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.147); catalogued as COSV101425709; called by muse, mutect2, varscan2
- CRAMP1 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV51960460, COSV99245864; called by muse, mutect2, varscan2
- CSMD1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs773296700, COSV68190724; called by muse, mutect2, varscan2
- DEAF1 | c.757A>G p.K253E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100101960; called by muse, mutect2, varscan2
- DLGAP5 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99903826; called by muse, mutect2
- DOCK5 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99376649; called by muse, mutect2, varscan2
- EFL1 | c.2308A>C p.S770R | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as COSV99186675; called by muse, mutect2, varscan2
- EPB41 | c.623G>A p.R208K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100548348; called by muse, mutect2, varscan2
- GPRC5B | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100315035; called by muse, mutect2, varscan2
- GRIK1 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100516470; called by muse, mutect2, varscan2
- GRIN2B | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.211); catalogued as COSV101663000; called by muse, mutect2, varscan2
- HASPIN | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99560807; called by muse, mutect2, varscan2
- IFT172 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99562183; called by muse, mutect2, varscan2
- IL1RL2 | c.291A>T p.I97= | Splice Region (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99960518; called by muse, mutect2, varscan2
- KMT2C | c.8307G>C p.K2769N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100070411; called by muse, mutect2, varscan2
- KMT2C | c.7443A>T p.R2481S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs748029485; called by muse, varscan2
- KMT2C | c.7443-1G>C p.X2481_splice | Splice Site (SNP) | VAF 12/43 reads (28%) | catalogued as COSV51333129, COSV51430440, COSV51435943; called by muse, varscan2
- LACTB2 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99399384; called by muse, mutect2
- LAMA5 | c.7130A>C p.H2377P | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV99439241; called by muse, mutect2, varscan2
- MEF2A | c.1277_1288del p.Q426_P429del (on ENST00000557942 / NM_001319206.2; = p.Q420_P423del on NM_005587.4 and 8 other RefSeq transcripts) | In Frame Del (DEL) | VAF 5/45 reads (11%) | catalogued as rs930300815; called by mutect2, pindel
- MRPL32 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 7/72 reads (10%) | catalogued as COSV99785789; called by muse, mutect2, varscan2
- MST1R | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as COSV99618407; called by muse, mutect2, varscan2
- NAALADL2 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs528769783, COSV69161344; called by muse, mutect2, varscan2
- NCOR1 | c.3925G>A p.E1309K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV51988991, COSV99249198; called by muse, mutect2, varscan2
- NDN | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs549529148, COSV100086387; called by muse, mutect2, varscan2
- NEK6 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs750746819, COSV100206774; called by muse, mutect2, varscan2
- NHLRC3 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 24/94 reads (26%) | catalogued as COSV100612750; called by muse, mutect2, varscan2
- OR4S1 | c.34T>A p.L12I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.589); catalogued as COSV100180212; called by muse, mutect2, varscan2
- PCDHA8 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.858); catalogued as rs1481565497, COSV65328405; called by muse, mutect2, varscan2
- PCNT | c.7199G>A p.R2400H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs757082073, COSV100855395, COSV64027236; called by muse, mutect2, varscan2
- PHYKPL | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1477386963; called by muse, mutect2
- PIK3C2G | c.3254C>T p.S1085L (on ENST00000676171; = p.S1044L on NM_004570.5) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs560894742, COSV56797178; called by muse, mutect2, varscan2
- PRAMEF20 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1158947849; called by muse, mutect2, varscan2
- PRKD1 | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs771765508, COSV59581764; called by muse, mutect2, varscan2
- PTRH1 | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100076807, COSV58852817; called by muse, mutect2, varscan2
- SBDS | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99885962; called by muse, mutect2, varscan2
- SIRPA | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 30/141 reads (21%) | catalogued as COSV100605124; called by muse, mutect2, varscan2
- SLC12A2 | c.3520C>T p.R1174* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as rs1340527453, COSV52468222; called by muse, mutect2, varscan2
- SUCLG2 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs778540373, COSV56204193; called by muse, mutect2, varscan2
- SVIL | c.4793A>T p.D1598V (on ENST00000355867 / NM_021738.3; = p.D1172V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100881193; called by muse, mutect2, varscan2
- UBR5 | c.4058+1G>A p.X1353_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV55297671; called by muse, mutect2, varscan2
- VWA3B | c.2305G>T p.A769S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs370641061, COSV101345995; called by muse, mutect2, varscan2
- XIRP2 | c.1354G>A p.D452N (on ENST00000628543; = p.D627N on NM_152381.6) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs376918960; called by muse, mutect2, varscan2
- ZAN | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.302); catalogued as COSV100769568; called by muse, mutect2, varscan2
- ZNF584 | c.7G>T p.G3W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100183258; called by muse, mutect2, varscan2
- ZNF721 | c.2278G>A p.E760K (on ENST00000338977; = p.E772K on NM_133474.4) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.893); catalogued as COSV100167289, COSV100167592; called by muse, mutect2, varscan2
- CCNB3 | c.1824G>T p.Q608H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CHRNG | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2
- CTRB2 | c.294C>G p.I98M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); called by mutect2, varscan2
- SLK | c.3174_3181del p.E1059Kfs*17 | Frame Shift Del (DEL) | VAF 30/63 reads (48%) | called by mutect2, pindel, varscan2
- SMTNL2 | c.473A>G p.H158R (on ENST00000389313 / NM_001114974.2; = p.H14R on NM_198501.3) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- ABCA6 | c.1248C>T p.Y416= | Silent (SNP) | VAF 8/175 reads (5%) | catalogued as COSV99446245; called by muse, mutect2
- ARID4B | c.294G>A p.E98= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV51608228, COSV99935402; called by muse, mutect2, varscan2
- BCL3 | c.432G>A p.V144= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs1032973347, COSV99378076; called by muse, mutect2
- DLX6 | c.252C>T p.G84= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99142279; called by muse, varscan2
- FLT1 | c.3339G>T p.L1113= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV99151372; called by muse, mutect2, varscan2
- LYPD4 | c.630G>T p.V210= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV100419380; called by muse, mutect2, varscan2
- MPHOSPH9 | c.3118C>T p.L1040= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as COSV100186681; called by muse, mutect2, varscan2
- SF3A3 | c.171G>A p.L57= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100885615, COSV65955470; called by muse, mutect2, varscan2
- SIGLEC5 | c.897G>A p.L299= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV99707396; called by muse, mutect2
- SLC6A6 | c.813C>T p.G271= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs776809674, COSV100692059; called by muse, mutect2, varscan2
- TMEM248 | c.378C>T p.F126= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs186391366; called by muse, mutect2, varscan2
- ZBTB33 | c.1143T>G p.L381= | Silent (SNP) | VAF 4/100 reads (4%) | catalogued as COSV100434137; called by muse, mutect2
